Somatic mutation profile of tumor specimen TCGA-2H-A9GF-01A (aliquot TCGA-2H-A9GF-01A-11D-A37C-09) from TCGA case TCGA-2H-A9GF, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 67.0 years (24,487 days).
Specimen TCGA-2H-A9GF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b6a420f-3139-45d8-8919-9475be9e78e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2H-A9GF-11A (Solid Tissue Normal), aliquot TCGA-2H-A9GF-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/676d65d1-5c4e-4742-aeb7-14dca168a8c6

The open-access MAF lists 310 somatic variants for this specimen: 225 protein-altering or splice-affecting, 76 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 205, Silent 76, Intron 7, Nonsense Mutation 6, Frame Shift Del 5, Frame Shift Ins 4, In Frame Del 3, RNA 1, Splice Site 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- INSR | c.3160G>A p.V1054M | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1135401741, CM068488; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.529_546del p.P177_C182del | In Frame Del (DEL) | VAF 14/22 reads (64%) | hotspot (GDC flag); called by mutect2, varscan2
- AASS | c.1103A>T p.E368V | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV62791815; called by muse, mutect2, varscan2
- ABCA13 | c.8815C>T p.R2939C | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs746169215, COSV71292474; called by muse, mutect2, varscan2
- ABCB6 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs145498806; called by muse, mutect2, varscan2
- ADAMTS2 | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs760741152; called by muse, mutect2, varscan2
- ADGRL2 | c.4291G>T p.D1431Y (on ENST00000370717 / NM_001366005.1; = p.D1375Y on NM_012302.4) | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs773682494; called by muse, mutect2, varscan2
- AGBL4 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs753216988, COSV61893285; called by muse, mutect2, varscan2
- AGO4 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs370159437; called by muse, mutect2, varscan2
- AMOTL2 | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as rs145301642; called by muse, mutect2, varscan2
- ANKS3 | c.1895G>A p.G632E | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs780698655; called by muse, mutect2, varscan2
- AP1G1 | c.1091G>C p.R364P | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1269321019, COSV100250083; called by muse, mutect2, varscan2
- AP3B2 | c.1015G>A p.V339I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1367868541; called by muse, mutect2, varscan2
- APCDD1L | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.784); catalogued as rs763585294, COSV64486006; called by muse, mutect2, varscan2
- ARID1A | c.1680C>A p.Y560* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as COSV61383943; called by muse, mutect2, varscan2
- BDP1 | c.7771G>A p.E2591K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.324); catalogued as COSV62435347; called by muse, mutect2, varscan2
- BUD13 | c.1073C>T p.S358F | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs1485691213, COSV52770546; called by muse, mutect2, varscan2
- C1orf94 | c.640G>A p.A214T (on ENST00000488417 / NM_001134734.2; = p.A24T on NM_032884.5) | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs202207825, COSV64913085; called by muse, mutect2, varscan2
- CAD | c.2308C>T p.R770C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1286557374, COSV53031022; called by muse, mutect2, varscan2
- CNTN3 | c.1250A>C p.K417T | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV99726284; called by muse, mutect2, varscan2
- CNTN4 | c.2495G>T p.R832L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61869453; called by muse, mutect2, varscan2
- COL6A3 | c.3808C>T p.R1270W | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781735632, COSV99800527; called by muse, mutect2, varscan2
- CRTC1 | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as rs1454418141, COSV58718253; called by muse, mutect2, varscan2
- CUX2 | c.3314G>A p.R1105H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866772697, COSV55637270; called by muse, mutect2
- DCAF12L2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs767789728, COSV63580668, COSV63582948; called by muse, mutect2, varscan2
- DDX55 | c.1663_1665del p.L555del | In Frame Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs762751499; called by pindel, varscan2
- DLG2 | c.1070A>G p.K357R | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV54665601, COSV54681076; called by muse, mutect2, varscan2
- DNAH11 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as rs753634502, COSV100177264; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSCAML1 | c.392C>T p.P131L (on ENST00000321322; = p.P71L on NM_020693.4) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750900813; called by muse, mutect2, varscan2
- EDIL3 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs757863733, COSV56879041; called by muse, mutect2, varscan2
- ERP27 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as rs758029188, COSV56764075; called by muse, mutect2, varscan2
- EYS | c.157T>G p.F53V | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); catalogued as COSV60998343; called by muse, mutect2
- FAM47A | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 116/143 reads (81%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs753875155, COSV60498289, COSV60499246; called by muse, mutect2, varscan2
- FERD3L | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51762396; called by muse, mutect2, varscan2
- FMR1NB | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV63272794; called by muse, mutect2, varscan2
- FNDC1 | c.4168C>T p.R1390* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as rs766895954, COSV51938784; called by muse, mutect2, varscan2
- GRM6 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs201846399; called by muse, mutect2, varscan2
- GRM7 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs955146413, COSV100735987; called by muse, mutect2, varscan2
- GUCY1A1 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as rs760929543; called by muse, mutect2, varscan2
- GUCY1A2 | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748015731, COSV56483067; called by muse, mutect2, varscan2
- H1-2 | c.63G>C p.K21N | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs370362598, COSV59192701; called by muse, mutect2, varscan2
- HDGFL1 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.02); catalogued as rs1041727437, COSV100014555; called by muse, mutect2, varscan2
- HECW1 | c.4538G>A p.R1513H | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs139970379; called by mutect2, varscan2
- HFM1 | c.3140C>T p.T1047M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs754765102, COSV54029040; called by muse, mutect2, varscan2
- HUWE1 | c.12639G>A p.M4213I | Missense Mutation (SNP) | VAF 35/43 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV53333728, COSV53351871; called by muse, mutect2, varscan2
- IL1RL1 | c.1040T>C p.V347A | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs188567206; called by muse, mutect2, varscan2
- ITK | c.516A>C p.E172D | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV70062893; called by muse, mutect2, varscan2
- KDM4A | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs368052422, COSV64958927, COSV64959626; called by mutect2, varscan2
- KY | c.1804C>T p.H602Y | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.714); catalogued as rs763243689; called by muse, mutect2, varscan2
- LAMA1 | c.8314C>T p.R2772C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.801); catalogued as rs760542877; called by muse, mutect2, varscan2
- LRFN5 | c.1291G>C p.A431P | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV99982826; called by muse, mutect2, varscan2
- MARK2 | c.1483G>A p.G495S (on ENST00000402010 / NM_001039469.2; = p.G494S on NM_004954.5) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV59281650; called by muse, mutect2, varscan2
- MAST1 | c.3841G>A p.A1281T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.019); catalogued as rs777266216; called by muse, mutect2, varscan2
- MASTL | c.1949G>C p.R650T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV60911616; called by muse, mutect2, varscan2
- MINDY4 | c.1861G>A p.D621N | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.351); catalogued as rs375320849, COSV99518539; called by muse, mutect2, varscan2
- MKRN3 | c.1160T>G p.L387R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1180324511, COSV58811586; called by muse, mutect2, varscan2
- MLF2 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as rs780289664; called by muse, mutect2, varscan2
- MUC16 | c.20849C>A p.T6950N | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.373); catalogued as COSV67442991; called by muse, mutect2, varscan2
- MUC16 | c.11080A>C p.S3694R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.429); catalogued as COSV67474994; called by muse, mutect2, varscan2
- MYH1 | c.5445G>T p.Q1815H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV99876945; called by muse, mutect2, varscan2
- MYH13 | c.5741C>A p.A1914E | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52835111; called by muse, mutect2, varscan2
- MYO1D | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1381617721, COSV59020580; called by muse, mutect2, varscan2
- NEO1 | c.2065G>T p.G689W | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56070425; called by muse, mutect2
- OR2T2 | c.339C>A p.F113L | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as rs1227401259, COSV61617737, COSV61618215; called by muse, mutect2
- OR5D13 | c.133T>G p.L45V | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as rs112091941, COSV62335074; called by muse, mutect2, varscan2
- OR5T2 | c.904A>C p.S302R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as rs867798059, COSV57588098; called by muse, mutect2, varscan2
- PCDH9 | c.3482T>G p.F1161C (on ENST00000377865 / NM_203487.3; = p.F1127C on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs776146493; called by muse, mutect2, varscan2
- PCDHGB2 | c.1222G>A p.G408S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.318); catalogued as rs1349523966; called by muse, mutect2, varscan2
- PCLO | c.12743del p.N4248Ifs*20 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | catalogued as COSV61672693, COSV61676847; called by mutect2, pindel, varscan2
- PDE6A | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs768596256, COSV54926143; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDILT | c.1493A>G p.E498G | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV56703873; called by muse, mutect2, varscan2
- PEX5L | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs766115029; called by muse, mutect2, varscan2
- PLCL1 | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.05); catalogued as rs780710675; called by muse, varscan2
- PLXNB1 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1175091336; called by muse, mutect2, varscan2
- PMEPA1 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1488824162; called by muse, mutect2, varscan2
- PNPT1 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1320187955, COSV53179422; called by muse, mutect2, varscan2
- PPP1R10 | c.2033C>T p.P678L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1405225650; called by muse, mutect2, varscan2
- PRKCG | c.1883C>T p.P628L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs1303074743; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKG2 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as rs768165134; called by muse, mutect2, varscan2
- PTPRD | c.5021G>A p.R1674H | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755582635, COSV61961955; called by muse, mutect2, varscan2
- PZP | c.4300A>C p.S1434R | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV54353742; called by muse, mutect2, varscan2
- RBM27 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs199578137; called by muse, mutect2, varscan2
- RCVRN | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs991604561, COSV56841871; called by muse, mutect2, varscan2
- RIMBP2 | c.3037T>G p.F1013V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55466023, COSV55470989, COSV55480263; called by muse, mutect2, varscan2
- ROBO1 | c.3508A>T p.R1170* | Nonsense Mutation (SNP) | VAF 15/81 reads (19%) | catalogued as COSV71398983; called by muse, mutect2, varscan2
- SDK1 | c.3685G>A p.V1229I | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs146383881; called by muse, mutect2, varscan2
- SIPA1L1 | c.854G>C p.R285P | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV62173174; called by muse, mutect2, varscan2
- SORCS3 | c.2614T>C p.F872L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63796502; called by muse, mutect2, varscan2
- SPTBN4 | c.2806C>T p.R936C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs373335509; called by muse, mutect2, varscan2
- SRRM2 | c.3410G>A p.R1137K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV57067727; called by muse, mutect2, varscan2
- STAC | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766859384; called by muse, mutect2, varscan2
- SYCE1 | c.108G>T p.L36F | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100385945, COSV58217824; called by muse, mutect2, varscan2
- TBX5 | c.1064G>T p.R355L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.68); catalogued as rs145784562; called by muse, mutect2, varscan2
- TEPSIN | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs566719497; called by muse, mutect2, varscan2
- TEX37 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.025); catalogued as rs1489749229, COSV57557019; called by muse, mutect2, varscan2
- TRANK1 | c.2849G>A p.R950H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as rs765403445, COSV100085015; called by muse, mutect2, varscan2
- TRIM3 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs770963103; called by muse, mutect2, varscan2
- TTN | c.49244G>A p.R16415Q (on ENST00000591111; = p.R8991Q on NM_003319.4) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | PolyPhen benign (0.131); catalogued as rs376932266, COSV59983027; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA8 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.7); catalogued as rs73876568; called by muse, mutect2, varscan2
- UNC5A | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1418893349; called by muse, mutect2, varscan2
- ZFP42 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1405742293, COSV100478758; called by muse, mutect2, varscan2
- ZFPM2 | c.2282T>C p.L761P | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.998); catalogued as rs1458301276; called by muse, mutect2, varscan2
- ZNF208 | c.1847A>G p.K616R | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV68100724, COSV68112724; called by muse, mutect2, varscan2
- ZNF217 | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs748890703, COSV56601225; called by muse, mutect2, varscan2
- ZNF341 | c.1024C>T p.R342* (on ENST00000375200 / NM_001282935.1; = p.R335* on NM_032819.4) | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as rs756537281; called by muse, mutect2, varscan2
- ZNF419 | c.1135T>G p.F379V | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.071); catalogued as COSV55659361; called by muse, mutect2, varscan2
- ZNF446 | c.396G>T p.E132D | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.637); catalogued as COSV52180434; called by muse, mutect2, varscan2
- ZNF490 | c.956C>T p.T319M | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs191151266; called by muse, mutect2, varscan2
- ZNF570 | c.542A>G p.K181R | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV57578130, COSV57579717; called by muse, mutect2, varscan2
- ZNF585A | c.1121G>T p.R374I (on ENST00000292841 / NM_001288800.2; = p.R319I on NM_152655.3) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs771852009, COSV53062550; called by muse, mutect2, varscan2
- ADPRM | c.662G>A p.W221* | Nonsense Mutation (SNP) | VAF 26/38 reads (68%) | called by muse, mutect2, varscan2
- ADRA1D | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- AHNAK | c.1945C>T p.H649Y | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- ANKRD11 | c.5311C>A p.L1771I | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASF1A | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- BCO1 | c.315_316del p.S107Qfs*52 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | called by pindel, varscan2
- BCOR | c.489dup p.E164Rfs*22 | Frame Shift Ins (INS) | VAF 39/59 reads (66%) | called by mutect2, pindel, varscan2
- BTN3A1 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CACTIN | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.156); called by muse, mutect2
- CAPN6 | c.392G>C p.W131S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CASK | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT tolerated (0.48); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CD1E | c.144C>G p.H48Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH13 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- CENPT | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- CHD9 | c.2669G>A p.G890D | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CMKLR1 | c.382T>G p.F128V (on ENST00000312143 / NM_001142344.2; = p.F126V on NM_004072.3) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- COL1A2 | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CSMD3 | c.849T>G p.F283L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DIAPH2 | c.2294C>T p.A765V | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious (0.02); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- DMRT1 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DNAH11 | c.535T>C p.S179P | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- DOCK3 | c.4805A>C p.K1602T | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2
- DPEP3 | c.277C>T p.L93F | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ECEL1 | c.1655A>C p.K552T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- EML4 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EP300 | c.2876G>A p.S959N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- EPB41L3 | c.388T>C p.S130P | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ETNPPL | c.536G>C p.R179T | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- EXTL3 | c.1061G>A p.R354K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0.001); called by muse, mutect2
- F8 | c.3180del p.V1061* | Frame Shift Del (DEL) | VAF 17/43 reads (40%) | called by mutect2, pindel, varscan2
- FAM184A | c.3410A>T p.Y1137F | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FIGN | c.1346C>A p.A449E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FLRT3 | c.1319G>T p.W440L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSTL1 | c.735G>T p.E245D | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- FSTL4 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- GATAD2A | c.1143C>G p.N381K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GLI3 | c.4349T>C p.F1450S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GLRB | c.778T>G p.F260V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GPRASP1 | c.781C>G p.P261A | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- GRAMD1A | c.1612C>G p.L538V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- HELB | c.137A>T p.E46V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HERC2 | c.3121G>C p.E1041Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- HPS3 | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- HPSE2 | c.308C>A p.T103N | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- HRH2 | c.807A>C p.L269F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.85); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- HSD17B4 | c.752G>A p.C251Y (on ENST00000414835 / NM_001199291.3; = p.C226Y on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ICAM5 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- IRF5 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- ITPR1 | c.4597G>A p.V1533M (on ENST00000354582; = p.V1518M on NM_002222.7) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM3B | c.2167G>A p.G723S | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT tolerated, low confidence (0.59); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF5C | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT18 | c.1081dup p.Q361Pfs*4 | Frame Shift Ins (INS) | VAF 15/35 reads (43%) | called by mutect2, pindel, varscan2
- L3MBTL4 | c.848T>G p.V283G | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- LARP7 | c.286A>G p.S96G | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- LRP1B | c.8201C>T p.S2734F | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- LRP1B | c.2660C>T p.P887L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- MAP4K5 | c.518A>C p.K173T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTIF2 | c.1169G>C p.G390A | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC16 | c.9407G>A p.R3136K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NBEAL1 | c.6526C>G p.L2176V | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NDST3 | c.1064A>G p.H355R | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- NELL2 | c.53C>A p.A18E | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOVA1 | c.890T>G p.V297G | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- NPAP1 | c.678G>C p.Q226H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NPBWR2 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR2T34 | c.247del p.V83Cfs*28 | Frame Shift Del (DEL) | VAF 13/94 reads (14%) | called by mutect2, pindel, varscan2
- OR56A1 | c.359T>G p.V120G | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- OR5D16 | c.229T>G p.S77A | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- OR5W2 | c.91T>C p.F31L | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PCDH18 | c.2652T>G p.D884E | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PCSK7 | c.1972T>C p.Y658H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.647); called by mutect2, varscan2
- PGR | c.1682C>A p.S561* | Nonsense Mutation (SNP) | VAF 38/70 reads (54%) | called by muse, mutect2, varscan2
- PPP2R3A | c.770A>G p.K257R | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.251); called by muse, mutect2
- PRKAA1 | c.1307A>C p.K436T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRKD1 | c.1619T>G p.L540R | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRR16 | c.152T>C p.L51P | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RALGPS2 | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- REV1 | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RIMS1 | c.532T>C p.W178R | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RIMS1 | c.4311A>C p.K1437N | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RPS11 | c.366_367dup p.G123Afs*13 | Frame Shift Ins (INS) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- SCN2A | c.4237C>A p.L1413M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA4A | c.744G>T p.E248D | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SEMA4D | c.1877C>T p.S626L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- SEMA6D | c.574T>G p.L192V | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- SFPQ | c.860G>A p.R287K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.9); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLC24A2 | c.1737-1G>A p.X579_splice | Splice Site (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- SLC26A7 | c.1624A>G p.K542E | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC8A1 | c.431C>A p.S144Y | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK3 | c.2696T>A p.F899Y | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SNTB1 | c.1262T>A p.L421H | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SOX11 | c.159G>T p.M53I | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SRCAP | c.2953C>T p.P985S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SSH2 | c.3101A>C p.E1034A | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ST6GALNAC1 | c.158A>T p.E53V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE1 | c.24883C>A p.L8295M (on ENST00000367255 / NM_182961.4; = p.L8224M on NM_033071.3) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF10 | c.390C>T p.I130= | Splice Region (SNP) | VAF 11/17 reads (65%) | called by muse, mutect2, varscan2
- TAF1L | c.4042C>A p.L1348I | Missense Mutation (SNP) | VAF 48/81 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- TANC1 | c.1769del p.L590* | Frame Shift Del (DEL) | VAF 20/47 reads (43%) | called by mutect2, pindel, varscan2
- THSD7A | c.2834C>T p.S945F | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- TOM1L1 | c.1051T>G p.S351A | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPR | c.693_695del p.E232del | In Frame Del (DEL) | VAF 7/28 reads (25%) | called by pindel, varscan2
- TRAM1L1 | c.943T>G p.L315V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- TRAV34 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- TTBK1 | c.3218T>A p.L1073Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); called by muse, mutect2
- UBE3B | c.2347G>C p.G783R | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UNC13C | c.4840C>A p.L1614M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- USP4 | c.1772C>A p.P591Q | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VEGFC | c.1088C>A p.T363K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- WRNIP1 | c.1710G>A p.M570I | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- ZC3H6 | c.3302C>A p.P1101Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.206); called by mutect2, varscan2
- ZCCHC14 | c.2437C>T p.P813S (on ENST00000268616; = p.P950S on NM_015144.3) | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ZNF384 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.12); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZNF74 | c.448G>C p.G150R | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ZRANB3 | c.1028_1029insG p.A345Cfs*18 | Frame Shift Ins (INS) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- AFF2 | c.2394G>T p.L798= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV54004240; called by muse, mutect2, varscan2
- AFG3L2 | c.1137G>A p.E379= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs749806569; called by muse, mutect2, varscan2
- AHNAK | c.17388G>A p.T5796= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs753164928; called by muse, mutect2, varscan2
- AKT2 | c.195C>T p.T65= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs755782228, COSV60910504; called by muse, mutect2, varscan2
- ALOX12 | c.69G>A p.Q23= | Silent (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- ANKRD42 | c.573G>A p.T191= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs145591736; called by muse, mutect2, varscan2
- APOB | c.5067C>A p.R1689= | Silent (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- APRT | c.498G>A p.E166= | Silent (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- B3GAT1 | c.615C>T p.F205= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs1269950689, COSV56994903; called by muse, mutect2, varscan2
- BIRC5 | c.246C>G p.S82= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV56956053; called by muse, mutect2, varscan2
- BRCA1 | c.63C>T p.I21= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs1555600921, COSV58792883; ClinVar: likely benign / not provided; called by muse, mutect2, varscan2
- C10orf71 | c.141C>T p.S47= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs769882503; called by muse, mutect2, varscan2
- CADM3 | c.288C>T p.S96= (on ENST00000368125 / NM_001127173.3; = p.S130= on NM_021189.5) | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs1557936246, COSV100930422; called by muse, mutect2, varscan2
- CAPN2 | c.1845C>T p.D615= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs369952708; called by muse, mutect2, varscan2
- CASS4 | c.1236G>A p.S412= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs770612500, COSV64385508; called by muse, mutect2, varscan2
- CD4 | c.1018C>T p.L340= | Silent (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- CIITA | c.1413C>T p.S471= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs1218343579; called by muse, mutect2, varscan2
- COBLL1 | c.861A>G p.K287= (on ENST00000392717; = p.K249= on NM_014900.5) | Silent (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- CPXCR1 | c.105T>C p.S35= | Silent (SNP) | VAF 34/39 reads (87%) | called by muse, mutect2, varscan2
- CSMD3 | c.10539C>A p.P3513= (on ENST00000297405 / NM_001363185.1; = p.P3344= on NM_052900.3) | Silent (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- CYP27B1 | c.582A>C p.G194= | Silent (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- DNAJC6 | c.1545G>A p.A515= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs201766287, COSV54776517; called by muse, mutect2, varscan2
- DOCK4 | c.3468T>C p.T1156= | Silent (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.4101G>A p.L1367= | Silent (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- EEF1AKNMT | c.459C>T p.G153= (on ENST00000361735 / NM_015935.5; = p.G67= on NM_014955.3) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs752354940; called by muse, mutect2, varscan2
- EHMT1 | c.3639C>T p.F1213= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV101135001; called by muse, mutect2, varscan2
- EPHB1 | c.942T>C p.P314= | Silent (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- EPHB1 | c.1155C>T p.G385= | Silent (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- FBN2 | c.4551C>T p.C1517= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs144018137; ClinVar: benign; called by muse, mutect2, varscan2
- GPR88 | c.129C>A p.I43= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100159407, COSV100159412; called by muse, mutect2, varscan2
- GRM1 | c.3501C>T p.S1167= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs746094718, COSV51151481; called by muse, mutect2
- GZMM | c.327G>A p.E109= | Silent (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- HTR1A | c.681C>T p.R227= | Silent (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2
- IGKV3-15 | c.243G>A p.R81= | Silent (SNP) | VAF 116/367 reads (32%) | catalogued as rs558967868; called by muse, mutect2, varscan2
- IMMP2L | c.474A>G p.K158= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs779329257; called by muse, mutect2, varscan2
- KCNA6 | c.540C>T p.S180= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as COSV99769090; called by muse, mutect2, varscan2
- LHX1 | c.1032C>T p.T344= | Silent (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- LPIN3 | c.1830C>A p.A610= | Silent (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- LRRC1 | c.438T>C p.N146= | Silent (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- LRRK2 | c.1227T>G p.S409= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV54152961; called by muse, mutect2
- MRPS5 | c.732G>A p.L244= | Silent (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- MUC2 | c.2799C>T p.D933= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs777566987; called by muse, mutect2, varscan2
- MYC | c.648C>T p.F216= (on ENST00000377970; = p.F231= on NM_002467.6) | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV52377047, COSV52381060; called by muse, mutect2, varscan2
- OPN1LW | c.816G>A p.V272= | Silent (SNP) | VAF 39/85 reads (46%) | called by muse, mutect2, varscan2
- OR13C9 | c.504C>T p.F168= | Silent (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- OR5H2 | c.594T>C p.S198= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs199527038, COSV62350757; called by muse, mutect2, varscan2
- PAPSS2 | c.12C>T p.I4= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV63263282; called by muse, mutect2, varscan2
- PCCA | c.531G>A p.K177= | Silent (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- PCDHGA12 | c.1842G>T p.P614= | Silent (SNP) | VAF 35/149 reads (23%) | called by muse, mutect2, varscan2
- PLIN1 | c.1530G>C p.L510= | Silent (SNP) | VAF 12/18 reads (67%) | called by muse, mutect2, varscan2
- POPDC2 | c.1026C>T p.L342= | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2
- PTBP3 | c.510T>C p.N170= | Silent (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- RIMS1 | c.801T>C p.P267= | Silent (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- ROBO2 | c.1047A>G p.K349= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV59937796, COSV59946770; called by muse, mutect2, varscan2
- SCN2A | c.2544T>G p.V848= | Silent (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- SDK1 | c.3687C>T p.V1229= | Silent (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- SGTB | c.462G>A p.K154= | Silent (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- SH3GL3 | c.549C>T p.V183= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as rs1413285213; called by muse, mutect2, varscan2
- SNRPN | c.528C>A p.P176= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1489705156; called by muse, mutect2, varscan2
- SSTR3 | c.753C>T p.S251= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as rs1195770408; called by muse, mutect2, varscan2
- STAB2 | c.5637T>C p.C1879= | Silent (SNP) | VAF 22/142 reads (15%) | called by muse, mutect2, varscan2
- TACR1 | c.156A>G p.V52= | Silent (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- TBC1D19 | c.1348C>A p.R450= | Silent (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- TBX4 | c.51G>A p.P17= | Silent (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- TCHH | c.1473C>T p.L491= | Silent (SNP) | VAF 44/174 reads (25%) | catalogued as rs747412691; called by muse, mutect2, varscan2
- TET3 | c.2286G>A p.S762= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs566225972; called by muse, mutect2, varscan2
- TEX15 | c.7956T>C p.F2652= (on ENST00000256246; = p.F3035= on NM_001350162.2) | Silent (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- TMED1 | c.534C>T p.F178= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs761494685, COSV53033598; called by muse, mutect2, varscan2
- TNR | c.99G>T p.L33= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99688240; called by muse, mutect2, varscan2
- TRPM3 | c.1146A>G p.E382= (on ENST00000357533 / NM_001366142.2; = p.E227= on NM_020952.6) | Silent (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- UPF1 | c.1797G>A p.S599= (on ENST00000599848 / NM_001297549.2; = p.S588= on NM_002911.4) | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as rs201992127; called by muse, mutect2, varscan2
- UTP20 | c.8232G>A p.K2744= | Silent (SNP) | VAF 22/55 reads (40%) | called by muse, varscan2
- VCL | c.2473C>T p.L825= | Silent (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- WDR36 | c.2475A>C p.S825= | Silent (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- WDR4 | c.348G>A p.K116= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs770880708; called by muse, mutect2, varscan2
- ZNF554 | c.759C>T p.S253= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV57886754; called by muse, mutect2, varscan2
- AC244258.1 | n.892A>C | RNA (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- ARMC8 | c.1135-1173T>C | Intron (SNP) | VAF 24/42 reads (57%) | called by muse, mutect2, varscan2
- ASIC2 | c.556-179542G>A | Intron (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- ASIC2 | c.556-179928G>A | Intron (SNP) | VAF 7/26 reads (27%) | called by muse, varscan2
- FAM184A | c.3342-611C>T | Intron (SNP) | VAF 8/26 reads (31%) | catalogued as rs760310672; called by muse, mutect2, varscan2
- HTR2C | c.-80+16966A>G | Intron (SNP) | VAF 11/15 reads (73%) | called by muse, mutect2, varscan2
- MTMR1 | c.1656+207G>A | Intron (SNP) | VAF 7/10 reads (70%) | called by muse, mutect2, varscan2
- RAD23B | c.*2014T>A | 3'UTR (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- RNF145 | c.-40+1448G>A | Intron (SNP) | VAF 27/56 reads (48%) | called by muse, mutect2, varscan2
